Somatic mutation profile of tumor specimen C3N-03792-01 (aliquot CPT0292720006) from CPTAC case C3N-03792, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.5 years (14,044 days).
Specimen C3N-03792-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e95e2ded-a7ce-4f84-82fc-55e3d5cac2a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03792-31 (Blood Derived Normal), aliquot CPT0292740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9875b34a-56aa-4e73-9d46-a5cc7a515bde

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Nonsense Mutation 4, RNA 3, 3'Flank 2, Splice Site 2, In Frame Del 2, Frame Shift Del 1, 5'Flank 1, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL4 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | catalogued as rs1554222130, CM164306; ClinVar: pathogenic; called by muse, mutect2
- AJAP1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV65452619; called by muse, mutect2, varscan2
- ANO5 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 119/349 reads (34%) | catalogued as COSV61088706; called by muse, mutect2, varscan2
- BCL11B | c.1736C>T p.A579V (on ENST00000357195 / NM_001282237.2; = p.A508V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/398 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs1214962641, COSV61737854; called by muse, mutect2, varscan2
- CHD6 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs199798781; called by muse, mutect2, varscan2
- CLASP1 | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs368425278; called by muse, mutect2, varscan2
- COL4A2 | c.5110C>T p.R1704C | Missense Mutation (SNP) | VAF 127/303 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780380833; called by muse, mutect2, varscan2
- DDHD1 | c.5G>A p.R2H (on ENST00000323669; = p.R233H on NM_030637.3) | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs749524286; called by muse, mutect2, varscan2
- F13B | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 217/247 reads (88%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs192220037, COSV66374039; called by muse, mutect2, varscan2
- FGFR4 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1255439106; called by muse, mutect2, varscan2
- FKBP1C | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs774967522, COSV100644723; called by muse, mutect2, varscan2
- FLNC | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 234/1035 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768813870, COSV57965471; called by muse, mutect2, varscan2
- GEN1 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1377505476, COSV58055349; called by muse, mutect2, varscan2
- HCN1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 115/432 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57529468; called by muse, mutect2, varscan2
- ICAM2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 204/443 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs773254258, COSV99857077; called by muse, mutect2, varscan2
- LRRTM4 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs760929307, COSV101297465; called by muse, mutect2, varscan2
- MARF1 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770961629, COSV60027403; called by muse, mutect2, varscan2
- NKD2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs769021504; called by muse, mutect2, varscan2
- OR2T33 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 112/341 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.19); catalogued as rs182745895; called by muse, mutect2, varscan2
- PER3 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 38/536 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as rs370974877, COSV62704919; called by muse, mutect2
- RB1 | c.1963dup p.Y655Lfs*13 | Frame Shift Ins (INS) | VAF 118/203 reads (58%) | catalogued as CI973229; called by mutect2, pindel, varscan2
- RTP1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56617942, COSV56618257; called by muse, mutect2, varscan2
- SPATA20 | c.1037C>T p.S346L (on ENST00000356488 / NM_001258372.1; = p.S362L on NM_022827.4) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs138557972; called by muse, mutect2, varscan2
- SPHKAP | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762844015, COSV100763991, COSV60889811; called by muse, mutect2, varscan2
- TNRC6A | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760467705, COSV59368699; called by muse, mutect2, varscan2
- ZNF106 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 12/216 reads (6%) | catalogued as COSV55519785; called by muse, mutect2
- ZNF135 | c.1699G>A p.E567K (on ENST00000313434 / NM_001289401.2; = p.E579K on NM_003436.4) | Missense Mutation (SNP) | VAF 153/435 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs145588549, COSV57880553; called by muse, mutect2, varscan2
- ADGRG1 | c.883_885del p.S295del | In Frame Del (DEL) | VAF 112/300 reads (37%) | called by pindel, varscan2
- AGMO | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANO8 | c.309C>A p.H103Q | Missense Mutation (SNP) | VAF 24/552 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2
- DEFB124 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); called by mutect2, varscan2
- DMXL1 | c.8059G>T p.V2687L | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERP44 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- GET3 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KDM4A | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KIZ | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- MED12 | c.4090C>T p.Q1364* | Nonsense Mutation (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- MFRP | c.337G>C p.V113L (on ENST00000449574; = p.V489L on NM_031433.4) | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MMS22L | c.3370G>C p.V1124L | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NT5DC1 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB8 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 307/1529 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PKHD1 | c.6192A>T p.L2064F | Missense Mutation (SNP) | VAF 180/410 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RBM46 | c.73T>A p.L25I | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SLC25A19 | c.-38-4T>G | Splice Region (SNP) | VAF 143/579 reads (25%) | called by muse, mutect2, varscan2
- SUPT20H | c.994-1G>C p.X332_splice (on ENST00000350612 / NM_001014286.3; = p.X333_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TP53 | c.466_471delinsGCG p.R156_V157delinsA | In Frame Del (DEL) | VAF 58/118 reads (49%) | called by pindel, varscan2*
- ZFR | c.747_749delinsTC p.Q249Hfs*71 | Frame Shift Del (DEL) | VAF 58/202 reads (29%) | called by pindel, varscan2*
- KLHL30 | c.1221G>A p.P407= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as rs755323378, COSV59976509; called by muse, mutect2, varscan2
- OR2A7 | c.198G>A p.A66= | Silent (SNP) | VAF 92/664 reads (14%) | called by muse, mutect2, varscan2
- PCDHB7 | c.2118C>T p.F706= | Silent (SNP) | VAF 205/1013 reads (20%) | catalogued as rs868962799, COSV50753682; called by muse, mutect2, varscan2
- RNMT | c.1296G>A p.E432= | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- SEL1L | c.2286G>A p.R762= | Silent (SNP) | VAF 106/265 reads (40%) | called by muse, mutect2, varscan2
- STKLD1 | c.861G>A p.T287= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as rs1554776633; called by muse, mutect2, varscan2
- TFDP3 | c.819C>T p.D273= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as rs762868660, COSV59535768; called by muse, mutect2
- TLN1 | c.1128C>T p.G376= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV100147918; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826340 G>A | 3'Flank (SNP) | VAF 312/359 reads (87%) | called by muse, mutect2, varscan2
- EPB41L4A | chr5:112420289 C>T | 5'Flank (SNP) | VAF 24/78 reads (31%) | catalogued as rs142353468; called by muse, mutect2, varscan2
- FAM157A | n.101C>A | RNA (SNP) | VAF 87/315 reads (28%) | called by muse, mutect2, varscan2
- LINC01621 | n.1214T>A | RNA (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- MTX1 | chr1:155215124 G>A | 3'Flank (SNP) | VAF 441/791 reads (56%) | called by muse, mutect2, varscan2
- SEMA4D | c.1620-19C>T | Intron (SNP) | VAF 109/253 reads (43%) | catalogued as rs371930225; called by muse, mutect2, varscan2
- TUBBP5 | n.1153G>A | RNA (SNP) | VAF 134/582 reads (23%) | catalogued as rs766951080; called by muse, varscan2
